Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T7, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T7-01A (Primary Tumor).

HPRAA Discrepancy		☒

Pathology

port

Pathology,

OB:

Physician.

Sex

Accession

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

- (A) THYROID, TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA (2.0 CM) WITH FOCAL EXTRATHYROIDAL EXTENSION
Lymphovascular invasion is not identified
Resection margins are free of tumor

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroidectomy specimen, 7.2 x 3.5 x 1.5 cm. Within the inferior one-half of the right lobe of the thyroid is a 2.0 x 1.5 x 1.0 cm oval circumscribed tumor with a friable tan cut surface. The tumor is confined within the thyroid; no extracapsular extension is identified. There is a secondary 0.2 cm tan nodule in the superior pole of the left lobe of the thyroid.

The thyroid parenchyma away from these two nodules is red-brown and unremarkable.

SECTION CODE: A1-A4, tumor, right lobe of thyroid; A5, thyroid parenchyma inferior to tumor, right lobe; A6, inferior pole, right lobe of thyroid; A7, superior aspect, right lobe of thyroid; A8, isthmus; A9, inferior pole, left lobe of thyroid; A10, 0.2 cm tan nodule, superior left lobe of thyroid.

CLINICAL HISTORY

Carcinoma, thyroid.

SNOMED CODES

T-B6000, M-80503

ICD-O-3
carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS

C73.9 4-3-12-RD

"Some tests reported here may have been developed and performance characteristics determined by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

Source: NCI Genomic Data Commons file a5a91e8a-3dc9-4ba4-8839-75ff1a59271f (TCGA-EL-A3T7.6B1080F8-AF82-4FE3-B91D-3CA2DBA4A37E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).